Somatic mutation profile of tumor specimen TCGA-A3-3367-01A (aliquot TCGA-A3-3367-01A-02D-1421-08) from TCGA case TCGA-A3-3367, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 72.5 years (26,489 days).
Specimen TCGA-A3-3367-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f2123259-c633-4170-87d2-557410630ebc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A3-3367-11A (Solid Tissue Normal), aliquot TCGA-A3-3367-11A-01D-1421-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/180e2abd-fc29-4ee1-ab53-d0d0b0e6f058

The open-access MAF lists 72 somatic variants for this specimen: 58 protein-altering or splice-affecting, 11 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 11, Frame Shift Del 5, Frame Shift Ins 3, Splice Site 3, Nonsense Mutation 2, Intron 2, In Frame Del 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC8 | c.4018G>C p.D1340H | Missense Mutation (SNP) | VAF 50/158 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.227); catalogued as COSV56847357; called by muse, mutect2, varscan2
- ALOX15B | c.28A>G p.T10A | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66479130; called by muse, mutect2, varscan2
- ANO1 | c.2318G>A p.R773Q | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376371042; called by muse, mutect2, varscan2
- ANO1 | c.2686G>A p.V896I | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.09); catalogued as rs374804618, COSV62444096; called by muse, mutect2, varscan2
- AOC3 | c.1511C>A p.T504N | Missense Mutation (SNP) | VAF 48/149 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV53825025; called by muse, mutect2, varscan2
- ARHGAP45 | c.886A>T p.M296L | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV57430104; called by muse, mutect2, varscan2
- ARHGEF5 | c.2576G>T p.R859M | Missense Mutation (SNP) | VAF 15/201 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV50208217; called by muse, mutect2
- ARMC4 | c.1466C>A p.A489D | Missense Mutation (SNP) | VAF 36/168 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV59458654; called by muse, mutect2, varscan2
- ATP5F1C | c.173G>T p.R58L | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as COSV59621119, COSV59621642; called by muse, mutect2, varscan2
- BNIP5 | c.935G>A p.G312E | Missense Mutation (SNP) | VAF 38/448 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.261); catalogued as COSV71325392; called by muse, mutect2
- BTC | c.118G>T p.E40* | Nonsense Mutation (SNP) | VAF 21/261 reads (8%) | catalogued as COSV67547364; called by muse, mutect2
- CDH23 | c.5545C>T p.P1849S | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM1512619, COSV56452079; called by muse, mutect2, varscan2
- CDH7 | c.1962T>A p.D654E | Missense Mutation (SNP) | VAF 54/134 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59882811; called by muse, mutect2, varscan2
- COL6A3 | c.7860G>A p.M2620I | Missense Mutation (SNP) | VAF 30/306 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.245); catalogued as rs768129302, COSV55082570, COSV55113274; called by muse, mutect2, varscan2
- DBF4B | c.1729G>A p.A577T | Missense Mutation (SNP) | VAF 102/306 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV59259354; called by muse, mutect2, varscan2
- DNAH3 | c.803C>T p.T268M | Missense Mutation (SNP) | VAF 62/294 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs541602132, COSV54509013; called by muse, mutect2, varscan2
- FNBP4 | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 18/155 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.826); catalogued as COSV55446963; called by muse, mutect2, varscan2
- FRMD7 | c.121G>T p.E41* | Nonsense Mutation (SNP) | VAF 28/152 reads (18%) | catalogued as COSV53745101, COSV53745884; called by muse, mutect2, varscan2
- GBGT1 | c.714G>C p.Q238H | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV64409979; called by muse, mutect2, varscan2
- GNB1L | c.980C>A p.A327E | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.011); catalogued as COSV61547959, COSV61549203; called by muse, mutect2, varscan2
- GREB1 | c.4667A>G p.H1556R | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs778133601, COSV52182661; called by muse, mutect2, varscan2
- HTR2A | c.1292A>G p.N431S | Missense Mutation (SNP) | VAF 11/402 reads (3%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV66326812; called by muse, mutect2
- IL3 | c.203T>A p.M68K | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV57308552; called by muse, mutect2, varscan2
- JMJD1C | c.7280A>T p.Q2427L | Missense Mutation (SNP) | VAF 70/260 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV59513426; called by muse, mutect2, varscan2
- KLHL38 | c.520G>C p.E174Q | Missense Mutation (SNP) | VAF 65/182 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as COSV58086398; called by muse, mutect2, varscan2
- MAP6 | c.2210A>G p.N737S | Missense Mutation (SNP) | VAF 154/438 reads (35%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV59074659; called by muse, mutect2, varscan2
- MCHR2 | c.274C>A p.Q92K | Missense Mutation (SNP) | VAF 78/204 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56000723; called by muse, mutect2, varscan2
- MME | c.1320C>A p.V440= | Splice Region (SNP) | VAF 65/201 reads (32%) | catalogued as COSV64706305, COSV64706635; called by muse, mutect2, varscan2
- MTUS1 | c.632C>A p.S211Y | Missense Mutation (SNP) | VAF 88/265 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.428); catalogued as rs1171454478, COSV50551917; called by muse, mutect2, varscan2
- NLRP9 | c.1138A>T p.S380C | Missense Mutation (SNP) | VAF 87/304 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as COSV60460736; called by muse, mutect2, varscan2
- ONECUT1 | c.490C>A p.L164I | Missense Mutation (SNP) | VAF 45/132 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.899); catalogued as COSV59948196; called by muse, mutect2, varscan2
- PBRM1 | c.1757T>C p.M586T | Missense Mutation (SNP) | VAF 53/97 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV56261504, COSV56265358; called by muse, mutect2, varscan2
- PGF | c.315+1G>A p.X105_splice | Splice Site (SNP) | VAF 49/144 reads (34%) | catalogued as COSV53124817; called by muse, mutect2, varscan2
- PIRT | c.149A>T p.E50V | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV74119846; called by muse, mutect2, varscan2
- RMDN1 | c.290G>C p.G97A | Missense Mutation (SNP) | VAF 127/427 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.32); catalogued as COSV52204740; called by muse, mutect2, varscan2
- ROCK1 | c.2850A>C p.K950N | Missense Mutation (SNP) | VAF 65/172 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.14); catalogued as COSV67694897; called by muse, mutect2, varscan2
- RPL22 | c.257T>C p.L86P | Missense Mutation (SNP) | VAF 24/166 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV52377200; called by muse, mutect2, varscan2
- SHANK3 | c.776G>A p.R259H | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1201586226, COSV53184510; called by muse, mutect2
- SLC16A1 | c.1245G>C p.M415I | Missense Mutation (SNP) | VAF 14/295 reads (5%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV63708827; called by muse, mutect2
- SNX7 | c.422T>A p.F141Y | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60266641; called by muse, mutect2
- SRP9 | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 73/220 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.013); catalogued as COSV59158802; called by muse, mutect2, varscan2
- TTC4 | c.197C>T p.S66L | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as COSV64884439; called by muse, mutect2
- VHL | c.408_409insTTTT p.V137Ffs*8 | Frame Shift Ins (INS) | VAF 128/289 reads (44%) | catalogued as COSV56544783, COSV56547644; called by mutect2, pindel, varscan2
- ZNF584 | c.105T>G p.N35K | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV59721966; called by muse, mutect2, varscan2
- ZNF765 | c.1334A>G p.K445R | Missense Mutation (SNP) | VAF 7/166 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.02); catalogued as COSV67182159; called by muse, mutect2
- ZNF91 | c.450G>C p.Q150H | Missense Mutation (SNP) | VAF 116/298 reads (39%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.866); catalogued as COSV56081673, COSV56089298; called by muse, varscan2
- ZP4 | c.1285G>T p.V429L | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV63911330; called by muse, mutect2, varscan2
- CAT | c.1434+3_1434+6del p.X478_splice | Splice Site (DEL) | VAF 40/127 reads (31%) | called by mutect2, pindel, varscan2
- CHRNB1 | c.334_339delinsT p.D112Cfs*7 | Frame Shift Del (DEL) | VAF 12/40 reads (30%) | called by pindel, varscan2*
- COL6A6 | c.1799_1802del p.K600Tfs*2 | Frame Shift Del (DEL) | VAF 31/119 reads (26%) | called by mutect2, pindel, varscan2
- KIF21B | c.3615_3620del p.F1205_R1207delinsL | In Frame Del (DEL) | VAF 16/69 reads (23%) | called by mutect2, pindel, varscan2
- RC3H1 | c.842_854del p.R281Pfs*3 | Frame Shift Del (DEL) | VAF 30/183 reads (16%) | called by mutect2, pindel, varscan2
- SETD2 | c.7632dup p.K2545* | Frame Shift Ins (INS) | VAF 21/127 reads (17%) | called by mutect2, pindel, varscan2
- SETD2 | c.7431+1_7431+11del p.X2477_splice | Splice Site (DEL) | VAF 22/126 reads (17%) | called by mutect2, pindel, varscan2
- SIGLEC8 | c.1198del p.D400Ifs*19 | Frame Shift Del (DEL) | VAF 70/253 reads (28%) | called by mutect2, pindel, varscan2
- SLC22A8 | c.1035dup p.M346Yfs*90 | Frame Shift Ins (INS) | VAF 41/144 reads (28%) | called by mutect2, pindel, varscan2
- WASHC2A | c.331G>T p.A111S | Missense Mutation (SNP) | VAF 21/214 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- XRCC5 | c.574_598del p.F192Sfs*8 | Frame Shift Del (DEL) | VAF 26/179 reads (15%) | called by mutect2, pindel
- CHRNA1 | c.957T>C p.I319= (on ENST00000261007 / NM_001039523.3; = p.I294= on NM_000079.4) | Silent (SNP) | VAF 44/120 reads (37%) | catalogued as COSV53682024; called by muse, mutect2, varscan2
- CLVS1 | c.303C>T p.R101= | Silent (SNP) | VAF 46/121 reads (38%) | catalogued as COSV57971891; called by muse, mutect2, varscan2
- CXCR6 | c.835C>T p.L279= | Silent (SNP) | VAF 37/75 reads (49%) | catalogued as COSV56114327; called by muse, mutect2, varscan2
- EPHA2 | c.2298C>T p.D766= | Silent (SNP) | VAF 14/147 reads (10%) | catalogued as rs748286795, COSV64452331; called by muse, mutect2, varscan2
- EXPH5 | c.4971C>T p.S1657= | Silent (SNP) | VAF 126/359 reads (35%) | catalogued as COSV56199655; called by muse, mutect2, varscan2
- GANAB | c.2172T>C p.P724= | Silent (SNP) | VAF 16/212 reads (8%) | catalogued as COSV60462672; called by muse, mutect2
- KLHL15 | c.1431G>T p.A477= | Silent (SNP) | VAF 32/184 reads (17%) | catalogued as rs1027723593, COSV60139490; called by muse, mutect2, varscan2
- LAYN | c.1032G>A p.V344= (on ENST00000375615 / NM_001258390.1; = p.V336= on NM_178834.5) | Silent (SNP) | VAF 54/158 reads (34%) | catalogued as COSV65104545; called by muse, mutect2, varscan2
- MYT1 | c.1947G>A p.T649= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as rs142303893; called by muse, mutect2, varscan2
- NMRAL1 | c.789C>T p.F263= | Silent (SNP) | VAF 96/312 reads (31%) | catalogued as rs1043380, COSV52059408; called by muse, mutect2, varscan2
- ZNF333 | c.1218C>T p.S406= | Silent (SNP) | VAF 38/99 reads (38%) | catalogued as COSV52885148; called by muse, mutect2, varscan2
- GPHN | c.729+1288dup | Intron (INS) | VAF 32/119 reads (27%) | called by mutect2, pindel, varscan2
- PPP2R2B | c.70+21474A>T | Intron (SNP) | VAF 51/162 reads (31%) | catalogued as COSV60757046; called by muse, mutect2, varscan2
- STAG3L2 | n.760_762delinsCT | RNA (DEL) | VAF 32/280 reads (11%) | called by pindel, varscan2*
